Somatic mutation profile of tumor specimen 0DM4XR from CCDI case PBBZUK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.4 years (4,159 days).
Specimen 0DM4XR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6000e55-54d0-41da-b07c-199a00cdb6c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM4X2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eeac73dd-fd92-41ef-9bea-0f13bf0107e4

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Frame Shift Del 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 76/391 reads (19%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 250/434 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DST | c.16343C>T p.T5448M (on ENST00000361203 / NM_001374722.1; = p.T3036M on NM_015548.5) | Missense Mutation (SNP) | VAF 19/529 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1235729866, COSV55021213; called by muse, mutect2
- LARP1B | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 34/288 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.302); catalogued as rs1365501175; called by muse, mutect2, varscan2
- OBSCN | c.18575G>A p.R6192Q | Missense Mutation (SNP) | VAF 138/628 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs780421124; called by muse, mutect2, varscan2
- SLC12A7 | c.3097G>A p.D1033N | Missense Mutation (SNP) | VAF 198/821 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs761917706, COSV53754009; called by muse, mutect2, varscan2
- SRPK2 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 130/687 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.075); catalogued as rs772745182, COSV61960454; called by muse, mutect2, varscan2
- TRIOBP | c.1727G>T p.R576I | Missense Mutation (SNP) | VAF 100/530 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV60373811; called by muse, mutect2, varscan2
- ZNF268 | c.2706_2707del p.Q903Kfs*18 | Frame Shift Del (DEL) | VAF 148/688 reads (22%) | catalogued as rs1319840431; called by pindel, varscan2
- CYP2R1 | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 388/2709 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF2AK2 | c.1364T>G p.M455R | Missense Mutation (SNP) | VAF 79/411 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RGS12 | c.3781_3803del p.W1261Rfs*67 | Frame Shift Del (DEL) | VAF 85/370 reads (23%) | called by mutect2, pindel, varscan2
- SLIT2 | c.2648T>A p.I883N | Missense Mutation (SNP) | VAF 115/624 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPM3 | c.1787T>G p.L596R (on ENST00000357533 / NM_001366142.2; = p.L429R on NM_020952.6) | Missense Mutation (SNP) | VAF 98/454 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- CYP2R1 | c.582C>A p.I194= | Silent (SNP) | VAF 419/3611 reads (12%) | called by muse, mutect2, varscan2
- ITGB6 | c.534G>C p.V178= | Silent (SNP) | VAF 146/629 reads (23%) | called by muse, mutect2, varscan2
- TRIM7 | c.1155C>T p.R385= | Silent (SNP) | VAF 27/470 reads (6%) | catalogued as rs756330289; called by muse, mutect2
- UFD1 | c.422+83C>G | Intron (SNP) | VAF 24/156 reads (15%) | called by muse, mutect2
- USP8 | c.3172-34G>A | Intron (SNP) | VAF 61/194 reads (31%) | called by muse, mutect2, varscan2
